Surgical pathology report (de-identified scan), TCGA case TCGA-24-2293, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site Washington University, specimen TCGA-24-2293-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY REPORT
FINAL

*** Converted Case * This report may not match the original report format**

Patient Name: [REDACTED]
Address: [REDACTED]
Gender: [REDACTED]
DOB: [REDACTED]
Physician(s): [REDACTED]

Service:
Location:
MRN :
Hospital #:
Patient Type:

Accession :
Taken:
Received:
Accessioned:
Reported: [REDACTED]

TCGA - 24 - 2293

DIAGNOSIS:

OVARY, LEFT, HYSTERECTOMY - ADENOCARCINOMA (SEE COMMENT)
FALLOPIAN TUBES, RIGHT & LEFT, HYSTERECTOMY
- ADENOCARCINOMA (SEE COMMENT)
UTERUS, MYOMETRIUM, HYSTERECTOMY - SEROSAL IMPLANTS OF METASTATIC
ADENOCARCINOMA (SEE COMMENT)
UTERUS, CERVIX, HYSTERECTOMY - SEROSAL IMPLANTS OF METASTATIC
ADENOCARCINOMA (SEE COMMENT)
UTERUS, ENDOMETRIUM, HYSTERECTOMY - PROLIFERATIVE PATTERN
- NO EVIDENCE OF MALIGNANCY
PERITONEUM, "PERITONEAL TUMOR", BIOPSY
- ADENOCARCINOMA (SEE COMMENT)
OMENTUM, BIOPSY - ADENOCARCINOMA (SEE COMMENT)
APPENDIX, APPENDECTOMY - SEROSAL IMPLANTS OF ADENOCARCINOMA
(SEE COMMENT)

By this signature, I attest that the above diagnosis is based upon my personal
examination of the slides (and/or other material indicated in the diagnosis).

***Report Electronically Reviewed and Signed Out By Conversion [REDACTED]

Microscopic Description and Comment:

Sections of the left ovary show preservation of the normal architecture with focal microscopic surface implants of adenocarcinoma. The tumor focally contains prominent numbers of psammoma bodies. Identical surface implants of adenocarcinoma are present on the left and right fallopian tubes, and on the serosal surfaces of the uterus, cervix, and appendix. The omentum is also diffusely involved by metastatic adenocarcinoma. There is no evidence of a primary malignancy in the ovary, fallopian tubes, endometrium, or cervix.

The findings of multifocal microscopic tumor implants largely limited to the surfaces of the left ovary and fallopian tubes is

[page 2 of 3]
highly suggestive of metastatic involvement of these structures. A similar pattern of multifocal surface involvement was seen in this patient's prior right oophorectomy specimen [REDACTED]. Overall, the findings of a widely metastatic adenocarcinoma displaying papillary serous differentiation with no demonstrable genital tract primary is most suggestive of a primary peritoneal serous neoplasm. [REDACTED]

History:

The patient is a [REDACTED] with surface adenocarcinoma involving the right ovary and omentum. Diagnosis: As above. Operative procedure: Examination under anesthesia, exploratory laparotomy, total abdominal hysterectomy and left salpingo-oophorectomy, debulking, omentectomy, and appendectomy. An intraoperative non-microscopic consultation was obtained and interpreted as: "Uterus, cervix, LSO, right tube - Hysterectomy specimen comprised of the stated structure; no gross neoplasm left ovary or endometrium; fallopian tubes mildly edematous, but not significantly enlarged; uterine serosa shaggy in some areas; normal ovarian tissue taken for tissue bank," [REDACTED]

Specimen(s) Received:

A: UTERUS, CERVIX, LEFT OVARY AND TUBE, RIGHT TU
B: PERITONEAL TUMOR
C: OMENTUM
D: APPENDIX

Gross Description:

The specimen is received in four containers of formalin, each labelled with the patient's name. The first container is labelled "uterus, cervix, LSO, R tube" and contains a 270 gram TAH/LSO and right salpingectomy specimen. The uterine fundus has a length of 6.5 cm, a maximal width of 5.7 cm, and a maximal A-P dimension of 4.3 cm. Its outer surface is focally covered with shaggy tan and brown fibrous adhesions that display no nodularity. The myometrium ranges in thickness from 1.7 cm at the level of the lower uterine segment to 2.5 cm at the level of the mid fundus. It contains a single well-circumscribed, 0.5 x 0.5 cm firm white smooth muscle nodule in the left fundic wall. Otherwise, it is composed of the usual firm tan smooth muscle tissue with no gross abnormalities. The endometrium displays a uniform thickness of 0.1 cm. It is composed of the usual soft, tan, velvety tissue with no areas of nodularity. The cervical cross-sectional area is 3.5 x 3.5 cm, and the cervical length is 3.0 cm. The ectocervix and endocervix are covered by glistening tan and white mucosa with no areas of nodularity or ulceration. The left ovary is 4 x 2.5 x 1.5 cm. Its external surface is covered with shiny tan serosa with focal areas of soft maroon hemorrhage. The cut surface is unremarkable and contains no gross abnormalities. The left fallopian tube is 6 x 1.2 x 1.2 cm. It is focally covered by fibrous adhesions and the surrounding paratubal tissue is edematous, but the luminal diameter is uniformly pinpoint with no areas of nodularity. The right fallopian tube is 5 cm long and 2 x 1.5 cm in cross-sectional dimension. It is also edematous and displays a focally dilated lumen with no areas of nodularity. Blocks submitted: CXA - anterior cervix; CXP - posterior cervix; EM1 and EM2 - anterior endometrium; EM3 and EM4 - posterior endometrium; LO1 thru LO4 - left ovary; LT1 and LT2 - left fallopian tube; RT1 and RT2 - right fallopian tube; MM1 thru MM3 - myometrium (serosal surface in MM2 and MM3). [REDACTED]

The second container is labelled "peritoneal tumor" and contains a 6.5 x 5 x 5 cm aggregate of firm rubbery tan and yellow tissue fragments. [REDACTED]

The third container is labelled "omentum" and contains a 15 x 15 x 12 cm aggregate of multiple fragments of omentum. The cut surface is composed of firm yellow and white tissue grossly suspicious for metastatic carcinoma. [REDACTED]

The fourth container is labelled "appendix" and contains a 6.5 cm long appendix with an average width of 0.4 cm. It is mostly covered with shiny pink-purple serosa with focal fatty adhesions. The luminal circumference is uniformly pinpoint and is filled with soft white barium-like material in its proximal portion. There is

[page 3 of 3]
no gross evidence of tumor.

SURGICAL PATHOLOGY REPORT

[REDACTED]

Source: NCI Genomic Data Commons file ba9e9e35-b76c-4150-924d-6f8d78cc8fbd (TCGA-24-2293.CAF7DD79-D1F9-4061-8B50-AA8E5A4F18B7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).